TCGA case TCGA-VS-A8EJ — Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma (TCGA-CESC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Cervix uteri; Tissue source site: Barretos Cancer Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2e08a89e-4035-4782-b54f-f98eef5db80d

Demographics
Sex at birth: female; Race: white; Country of residence at enrollment: Brazil; Age at index: 60 years; Vital status: Dead; Days to death: 607 days (1.7 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; ICD-10 code: C53.9; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 60.2 years (22,000 days); Year of diagnosis: 2008; Method of diagnosis: Biopsy; AJCC pathologic T: T2b; AJCC pathologic N: NX; AJCC pathologic M: M1; FIGO stage: Stage IIB; FIGO staging edition year: 2009; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Days to treatment start: 136 days; Days to treatment end: 155 days; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Fluorouracil; Days to treatment start: 169 days; Days to treatment end: 322 days; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 423 days (1.2 years); Days to treatment end: 463 days (1.3 years); Treatment dose: 4,500 cGy; Treatment outcome: Progressive Disease; Number of fractions: 25; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Brachytherapy, High Dose; Treatment intent type: Adjuvant; Treatment dose: 2,700 cGy; Treatment outcome: Progressive Disease; Chemo concurrent to radiation: Yes; Timepoint category: Postoperative.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Cisplatin; Treatment intent type: Adjuvant; Number of cycles: 4; Treatment outcome: Progressive Disease; Chemo concurrent to radiation: Yes; Timepoint category: Postoperative; Treatment frequency: Once Weekly.
   Treatment given: Treatment type: Radiation, 3D Conformal; Treatment intent type: Adjuvant; Treatment dose: 4,500 cGy; Treatment outcome: Progressive Disease; Chemo concurrent to radiation: Yes; Timepoint category: Postoperative; Treatment anatomic sites: Pelvis.

Follow-up (2 entries)
- Day 0 (prior to adjuvant therapy): ECOG performance status: 0.
- Days to follow up: 607 days (1.7 years); Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 3; Pregnancy outcome: Live Birth.
- Timepoint category: Initial Diagnosis; Menopause status: Postmenopausal; Pregnant at diagnosis: No.
- Timepoint category: Initial Diagnosis; Weight: 113 kg; Height: 167 cm; BMI: 40.5.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-VS-A8EJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 60 mg.
  Slide TCGA-VS-A8EJ-01A-01-TS1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 20; Percent stromal cells: 10; Percent lymphocyte infiltration: 20; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 40.
- Sample TCGA-VS-A8EJ-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-VS-A8EJ-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); History neoadjuvant treatment: No; Tumor status: With tumor; Live birth pregnancy count: 3; Total pregnancy count: 3; Tobacco smoking history indicator: 1; Performance status timing: Pre-Adjuvant Therapy; Submitted tumor site: Cervical; Histologic diagnosis: Cervical Squamous Cell Carcinoma; Method initial path diagnosis: Biopsy (cervical / CT-guided / Other); Cause of death: Cervical Cancer; New tumor event diagnosis indicator: No.
- Treatment, Radiation therapy info: Brachytherapy type: HDR; Radiation therapy xrt type: 3D conformal.
- Treatment, Concurrent prescription treatment info, Concurrent prescription treatment: Chemo concurrent fractions total: 4.
- Drug treatment 1: Treatment best response: Clinical Progressive Disease.
- Drug treatment 3: Pharmaceutical therapy drug name: Fluoruracil; Treatment best response: Clinical Progressive Disease.
- Radiation treatment: Treatment best response: Radiographic Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 607 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 607 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 607 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-VS-A8EJ-01A-11D-A37M-01): tumor purity 0.92, ploidy 2.69, whole-genome doublings 1.
